Gene-level copy-number profile of tumor specimen TCGA-24-1466-01A from TCGA case TCGA-24-1466, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 74.8 years (27,307 days).
Specimen TCGA-24-1466-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.b18710e4-2d8f-4f32-8ba1-c526d43d4d0e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-24-1466-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f1013518-834b-4449-a9a6-6b49b6fd033d

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,883; copy number 2: 16,665; copy number 3: 17,015; copy number 4: 14,795; copy number 5: 5,230; copy number 6: 2,726; copy number 7: 968; copy number 8: 213; copy number 9: 111; copy number 10: 166; copy number 11: 42.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-24-1466-01A-01D-0472-01): tumor purity 0.85, ploidy 3.28, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,469 genes in 53 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:53,851,719–54,639,192, 28 genes, copy number 7 (within-gene range 4–7): YIPF1, DIO1, HSPB11, LRRC42, HNRNPA3P12, LDLRAD1, TMEM59, AL353898.3, TCEANC2, MIR4781, AL353898.1, AL353898.2, AL357673.1, CDCP2, AL357673.2, CYB5RL, MRPL37, SSBP3, SSBP3-AS1, AL161644.1, AL035415.1, AC099796.2, LINC02784, AC099796.1, HNRNPA1P63, ACOT11, FAM151A, AL590093.1.
- chr1:103,926,567–104,226,678, 3 genes, copy number 7: AL136455.1, AC092506.1, FTLP17.
- chr1:111,909,336–112,360,625, 3 genes, copy number 8 (within-gene range 6–8): KCND3-AS1, LINC01750, LINC02884.
- chr1:178,094,104–181,092,900, 70 genes, copy number 8–11 (within-gene range 4–11) (broad region; genes not listed).
- chr2:176,269,395–177,392,697, 27 genes, copy number 7 (within-gene range 5–7): MTX2, PPIAP67, LINC01117, AC017048.1, AC017048.2, MIR1246, AC017048.3, LINC01116, RNU6ATAC14P, AC092162.2, FUCA1P1, AC092162.1, AC092162.3, AC073636.1, RNU6-187P, AC074286.1, AC079305.2, RNA5SP112, STUB1P1, Y_RNA, KRT8P40, HNRNPA3, MIR4444-1, NFE2L2, DNAJC19P5, MIR3128, AC079305.1.
- chr2:177,300,600–177,313,882, 3 genes, copy number 7: AC019080.3, AC019080.4, MIR6512.
- chr3:21,942,566–22,991,582, 6 genes, copy number 7: ZNF385D-AS2, HMGB1P5, AC092421.1, AC114477.1, RANP7, SALL4P5.
- chr3:111,674,676–115,147,288, 80 genes, copy number 9 (broad region; genes not listed).
- chr3:150,202,174–150,603,228, 8 genes, copy number 9: AC117386.1, LINC01213, U2, LINC01214, AC018545.1, TSC22D2, SERP1, EIF2A.
- chr3:168,666,559–169,869,935, 23 genes, copy number 8: RPSAP33, RPL21P43, LINC02082, AC092954.1, AC092954.2, LINC01997, MECOM, MECOM-AS1, RPL22P1, AC007849.1, SDHDP3, RNU6-637P, TERC, Telomerase-vert, ACTRT3, AC078802.1, MYNN, AC078795.1, LRRC34, AC078795.3, AC078795.2, LRRIQ4, LRRC31.
- chr3:184,546,714–187,449,450, 75 genes, copy number 8 (broad region; genes not listed).
- chr4:29,748,757–30,008,316, 4 genes, copy number 7: EEF1A1P21, AC097510.1, RPS3AP17, AC106868.1.
- chr5:33,888,056–36,242,279, 45 genes, copy number 7 (within-gene range 6–7): RNU6-923P, RXFP3, SLC45A2, AC139783.2, AMACR, C1QTNF3-AMACR, AC139783.1, C1QTNF3, AC139792.2, AC139792.3, AC139792.1, AC138409.2, AC138409.1, AC138409.3, AC138853.1, AC025754.2, RAI14, AC025754.1, AC026801.2, TTC23L, AC026801.1, RPL21P54, RAD1, BRIX1, DNAJC21, AGXT2, PRLR, AC010368.1, U3, SPEF2, RNU7-130P, AC137810.1, IL7R, AC112204.3, AC112204.1, CAPSL, AC112204.2, UGT3A1, UGT3A2, AC016612.1, LMBRD2, MIR580, SKP2, RNU6-1305P, NADK2.
- chr6:62,460,940–65,707,226, 27 genes, copy number 7: DHFRP5, AL355375.1, AL355375.2, AL450346.1, FKBP1C, SPTLC1P3, AL450346.2, LGSN, AL121949.3, AL121949.2, AL121949.1, EEF1B2P5, PTP4A1, RPL7AP34, AL135905.1, AL135905.2, AL513043.1, RPL9P18, PHF3, EYS, AL354719.1, SCAT8, GCNT1P4, AL357375.1, HNRNPDP2, AL355357.1, AL365217.1.
- chr7:125,151,326–128,531,069, 49 genes, copy number 7–9: LINC02830, AC019155.1, AC019155.2, AC010099.1, AC010099.2, PPIAP93, AC003975.1, AC000372.1, GRM8, AC002057.2, AC000374.1, AC002057.1, AC000367.1, AC000362.1, MIR592, GRM8-AS1, PRELID3BP10, ZNF800, AC000123.2, AC000123.1, AC000123.3, AC000124.1, GCC1, ARF5, FSCN3, PAX4, AC073934.1, SND1, AC006529.1, SND1-IT1, LRRC4, MIR593, MIR129-1, LEP, AC018635.2, RBM28, AC018635.1, RNU7-27P, PRRT4, IMPDH1, AC010655.1, RNU7-54P, AC010655.4, HILPDA, AC010655.2, AC010655.3, METTL2B, Metazoa_SRP, AC090114.2.
- chr7:137,227,341–139,544,985, 52 genes, copy number 10: PTN, SNORD81, AC078842.2, AC078842.1, DGKI, AC090498.1, AC009245.1, CREB3L2, CREB3L2-AS1, AKR1D1, AC009263.1, AC024082.1, AC024082.2, RN7SKP223, RCC2P3, MIR4468, AC083867.2, Y_RNA, AC083867.1, AC008155.1, PTMAP10, IMPDH1P3, TRIM24, RPS3AP28, SVOPL, AC013429.2, AC013429.1, AC020983.1, UQCRFS1P2, ATP6V0A4, TMEM213, KIAA1549, RNU6-1272P, ZC3HAV1L, ZC3HAV1, AC018644.1, TTC26, AC009220.2, AC009220.3, AC009220.1, MZT1P2, UBN2, RNU6-206P, FMC1, LUC7L2, FMC1-LUC7L2, AC083880.1, RNU6-911P, KLRG2, AC005531.1, CLEC2L, ERHP1.
- chr7:148,696,467–149,624,752, 32 genes, copy number 8 (within-gene range 4–8): AC005229.4, CUL1, EZH2, RNU7-20P, Metazoa_SRP, RN7SL569P, AC073140.2, AC073140.1, RNY4, RNY3, RNY1, GHET1, PDIA4, RNU6-650P, COX6B1P1, ZNF786, ZNF425, RN7SL521P, ZNF398, AC004890.1, ZNF282, ZNF212, ZNF783, AC004890.3, AC004890.2, AC004941.2, NPM1P12, AC004941.1, AC073314.1, ZNF777, ZNF746, ZNF767P.
- chr8:9,136,255–11,203,671, 52 genes, copy number 7: PPP1R3B, AC022784.5, AC022784.1, AC022784.6, AC022784.2, AC022784.4, AC022784.3, RNU6-1151P, AC021736.1, AC021242.2, RNU6-526P, AC021242.1, AC021242.3, TNKS, AC103834.1, MIR597, MIR124-1HG, MIR124-1, AC034111.2, AC034111.1, MSRA, AC023385.1, AC079200.1, AC112673.1, AC104964.2, LINCR-0001, PRSS52P, RNU6-729P, AC104964.1, PRSS51, AC104964.3, PRSS55, RP1L1, MIR4286, C8orf74, RNA5SP252, SOX7, AC105001.2, AC105001.1, PINX1, MIR1322, AC011008.1, AC011008.2, XKR6, MIR598, AF131215.3, AF131215.6, AF131215.5, AF131215.4, AF131215.2, AF131215.1, AF131215.7.
- chr8:39,522,976–40,520,158, 18 genes, copy number 8 (within-gene range 5–8): AC123767.1, ADAM18, ADAM2, AP005902.2, AP005902.1, IDO1, AC007991.3, AC007991.2, AC007991.4, IDO2, AC007991.1, AC087518.1, LINC02866, TCIM, AC022733.1, SIRLNT, AC105999.1, AC010857.1.
- chr8:92,765,651–96,160,806, 76 genes, copy number 7–9 (broad region; genes not listed).
- chr8:107,160,354–107,498,055, 4 genes, copy number 7 (within-gene range 5–7): AP000428.2, HMGB1P46, AP000428.1, ANGPT1.
- chr8:126,325,454–131,144,948, 65 genes, copy number 7 (broad region; genes not listed).
- chr10:4,962,436–6,625,346, 57 genes, copy number 7: U8, AKR1C1, AKR1C2, AL391427.1, U8, AKR1C3, U8, AKR1C5P, AKR1C8P, AKR1C4, ARL4AP3, AL355303.2, AL355303.1, LINC02561, AKR1C7P, RPL26P28, AL683826.1, UCN3, TUBAL3, NET1, CALML5, CALML3-AS1, CALML3, AL732437.1, AL732437.3, AL732437.2, LASTR, AL365356.2, RN7SL445P, ASB13, TASOR2, AL365356.1, GDI2, NRBF2P5, AL596094.1, ANKRD16, RPL12P28, FBH1, AL137186.2, IL15RA, IL2RA, AL137186.3, AL137186.1, RPL32P23, RBM17, PFKFB3, RN7SKP78, MIR3155A, MIR3155B, AL157395.1, Y_RNA, LINC02649, SDCBPP1, LINC02656, PRKCQ, PRKCQ-AS1, LINC02648.
- chr10:9,721,963–15,371,289, 107 genes, copy number 10 (broad region; genes not listed).
- chr10:19,489,101–23,133,804, 67 genes, copy number 7–10 (within-gene range 3–10) (broad region; genes not listed).
- chr11:48,420,210–49,893,777, 49 genes, copy number 7: OR4C2P, OR4C10P, OR4C9P, OR4R1P, OR4A47, OR4A48P, OR4A46P, OR4A40P, OR4A43P, OR4A45P, OR4A41P, OR4A42P, OR4A44P, AC027369.6, AC027369.3, AC027369.4, AC027369.5, TRIM51CP, AC027369.2, TRIM51GP, TRIM53CP, AC027369.1, TRIM49B, AC084851.4, TRIM64C, AC084851.3, AC084851.1, UBTFL7, AC084851.2, AC118273.1, AC118273.2, TRIM77BP, UBTFL9, FOLH1, AC118942.1, TYRL, CBX3P8, AC135977.1, AC136759.1, AC130364.1, AC130364.2, TRIM51FP, AP006587.5, AP006587.6, AP006587.4, AP006587.3, TRIM51DP, AP006587.1, AP006587.2.
- chr11:73,218,281–74,498,533, 50 genes, copy number 7 (within-gene range 5–7): P2RY2, AP002761.4, OR8R1P, P2RY6, AP002761.3, ARHGEF17, RELT, AP000763.4, FAM168A, AP000763.3, AP000763.1, AP000763.2, HMGN2P38, AP000860.1, PLEKHB1, RAB6A, AP002993.1, AP002770.1, MRPL48, RN7SKP243, CCDC58P5, COA4, PAAF1, ARPC3P4, DNAJB13, AP003717.1, UCP2, AP003717.4, AP003717.2, AP003717.3, UCP3, C2CD3, AP002392.1, PPME1, RNA5SP343, AP000577.2, P4HA3, AP000577.1, P4HA3-AS1, PGM2L1, HNRNPA1P40, AP001372.1, AP001085.1, MIR548AL, KCNE3, AP001372.3, CYCSP27, AP001372.4, LIPT2, AP001372.2.
- chr11:82,603,529–83,107,789, 16 genes, copy number 7 (within-gene range 5–7): AP000793.1, RPS28P7, FAM181B, LINC02734, RBMXP3, PRCP, EIF2S2P6, DDIAS, AP000893.1, AP000893.2, RAB30, AP001767.1, SNORA70E, RAB30-DT, AP001767.2, AP001767.3.
- chr11:90,131,515–90,226,538, 4 genes, copy number 7 (within-gene range 5–7): NAALAD2, AP000648.4, CHORDC1, AP002364.1.
- chr11:92,366,496–92,498,935, 3 genes, copy number 7: PGAM1P9, AP000722.1, RPS3AP42.
- chr12:19,775,451–20,012,261, 2 genes, copy number 7 (within-gene range 4–7): AC024901.1, TCP1P3.
- chr12:68,143,318–70,637,440, 63 genes, copy number 7 (broad region; genes not listed).
- chr13:31,952,580–31,975,448, 3 genes, copy number 8: EEF1DP3, AC002525.1, Metazoa_SRP.
- chr13:43,877,715–46,897,076, 79 genes, copy number 7 (broad region; genes not listed).
- chr16:19,716,456–20,073,890, 5 genes, copy number 9 (within-gene range 2–12): IQCK, AC027130.1, LARP7P2, GPRC5B, GPR139.
- chr18:3,066,807–3,478,978, 15 genes, copy number 8 (within-gene range 6–8): MYOM1, RNU7-25P, AP005329.2, AP005329.3, MYL12A, AP005329.1, MYL12B, AP001025.1, LINC01895, RPL31P59, IGLJCOR18, RPL21P127, TGIF1, BOD1P1, GAPLINC.
- chr18:3,571,215–3,598,363, 3 genes, copy number 8 (within-gene range 6–8): RN7SL39P, AP002472.1, DLGAP1-AS1.
- chr20:4,721,909–5,316,954, 20 genes, copy number 7: PRND, PRNT, IDI1P3, AL133396.1, RASSF2, SLC23A2, AL389886.1, AL121890.1, AL121890.3, AL121890.2, AL121890.5, AL121890.4, TMEM230, RNA5SP474, Y_RNA, PCNA, AL121924.1, CDS2, UBE2D3P1, PROKR2.
- chr20:8,248,704–9,481,242, 6 genes, copy number 7: PLCB1-IT1, RNU105B, AL445567.1, AL445567.2, Metazoa_SRP, PLCB4.
- chr22:36,913,628–40,636,719, 155 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,883. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
